Gene-level copy-number profile of tumor specimen CDDP-ACRT-TTP1-A from CDDP_EAGLE case CDDP-ACRT, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 56 years.
Specimen CDDP-ACRT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0f518f5a-6f33-435e-906e-21133d8f6c73.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACRT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/d5b12488-bd7e-49ec-9b70-67fbcc7cb716

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,723; copy number 2: 52,129; copy number 3: 2,613; copy number 4: 274; copy number 5: 17; copy number 6: 37; copy number 7: 66; copy number 8: 20; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 142 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:69,875,271–69,920,867, 2 genes, copy number 11: GUSBP13, AC131392.1.
- chr7:102,479,976–102,592,444, 6 genes, copy number 5–6 (within-gene range 2–6): RASA4B, POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3.
- chr8:99,960,936–100,131,268, 1 gene, copy number 6 (within-gene range 2–6): RGS22.
- chr8:100,133,351–100,776,865, 23 genes, copy number 6–7: FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23.
- chr8:104,330,324–106,272,902, 24 genes, copy number 5–8 (within-gene range 4–8): DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2.
- chr8:123,680,794–123,815,452, 2 genes, copy number 5: ANXA13, FAM91A1.
- chr8:124,973,295–130,443,674, 75 genes, copy number 5–8 (broad region; genes not listed).
- chr15:20,901,441–20,970,215, 5 genes, copy number 8: ZNF519P2, NF1P1, MIR5701-1, OR11J2P, OR11J5P.
- chr15:22,125,511–22,126,434, 1 gene, copy number 5 (within-gene range 3–5): OR4N3P.
- chr15:22,160,431–22,185,402, 3 genes, copy number 6–7: IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8.

Autosomal genes at a single copy (total copy number 1): 930. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
